Somatic mutation profile of tumor specimen TCGA-EY-A1GJ-01A (aliquot TCGA-EY-A1GJ-01A-12D-A142-09) from TCGA case TCGA-EY-A1GJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 73.1 years (26,715 days).
Specimen TCGA-EY-A1GJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d677a81-c04d-4cbc-af05-85a18c647fec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GJ-10A (Blood Derived Normal), aliquot TCGA-EY-A1GJ-10A-01D-A142-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21b267ac-c822-48d2-92f9-057ceb0992d4

The open-access MAF lists 48 somatic variants for this specimen: 41 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 6, Nonsense Mutation 3, In Frame Ins 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1634A>G p.Y545C (on ENST00000281708 / NM_001349798.2; = p.Y465C on NM_018315.5) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560758208, COSV55890892, COSV55908001, COSV55914345; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>G p.R183G | Missense Mutation (SNP) | VAF 4/46 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 20/24 reads (83%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRG2 | c.2366C>T p.T789M (on ENST00000379869 / NM_001079858.3; = p.T786M on NM_005756.4) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780666105, COSV61338004; called by muse, mutect2, varscan2
- ANO4 | c.459C>T p.S153= (on ENST00000392977 / NM_001286615.2; = p.S118= on NM_178826.4) | Splice Region (SNP) | VAF 31/69 reads (45%) | catalogued as COSV100152884; called by muse, mutect2, varscan2
- ASB2 | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758888523, COSV100279344; called by muse, mutect2, varscan2
- ATP2B3 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV54855698, COSV99684441; called by muse, mutect2, varscan2
- BNC2 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs771427273, COSV101033255; called by muse, mutect2, varscan2
- C16orf71 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs750333138, COSV54789162; called by muse, mutect2, varscan2
- CMKLR1 | c.452G>A p.R151H (on ENST00000312143 / NM_001142344.2; = p.R149H on NM_004072.3) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771883601, COSV56437995; called by muse, mutect2, varscan2
- CRACD | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV51716446, COSV99949292; called by muse, mutect2, varscan2
- CXCL3 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99932795; called by muse, mutect2, varscan2
- INTS6L | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143312165, COSV100878115; called by muse, mutect2, varscan2
- KCNQ1 | c.1585T>C p.F529L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV99326931; called by muse, mutect2, varscan2
- KHDC4 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.45); catalogued as COSV100850807; called by muse, mutect2, varscan2
- KRT81 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs374156610; called by muse, mutect2, varscan2
- LCE1C | c.41C>G p.P14R | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100908443, COSV64218217; called by muse, mutect2, varscan2
- LGALS3BP | c.1658C>A p.S553* | Nonsense Mutation (SNP) | VAF 23/28 reads (82%) | catalogued as rs143986382, COSV99431669; called by muse, mutect2
- MMP3 | c.1083G>T p.W361C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100242836; called by muse, mutect2
- MTRF1 | c.1321C>T p.L441F | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV101067512; called by muse, mutect2, varscan2
- MYCBP2 | c.5522A>G p.Q1841R (on ENST00000357337; = p.Q1879R on NM_015057.5) | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV100630386; called by muse, varscan2
- MYOM3 | c.3554G>A p.G1185E | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58392368; called by muse, mutect2, varscan2
- PCDHA6 | c.590A>T p.K197M | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV100972272; called by muse, varscan2
- PCDHA9 | c.2292G>T p.K764N | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100969518, COSV65325406; called by mutect2, varscan2
- PCDHGA2 | c.85G>T p.G29W | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.538); catalogued as COSV53938535, COSV54044811; called by muse, mutect2, varscan2
- PDE6B | c.1041C>G p.Y347* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV99727547; called by muse, mutect2, varscan2
- POLA1 | c.2761C>G p.R921G | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100985435, COSV66884973; called by muse, mutect2, varscan2
- RBM47 | c.1637C>A p.A546D (on ENST00000295971 / NM_001098634.2; = p.A477D on NM_019027.4) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as COSV99920812; called by muse, mutect2
- RNF113A | c.473A>G p.N158S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV101007041; called by muse, mutect2, varscan2
- SIPA1 | c.2936C>G p.S979C | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV100425838; called by muse, mutect2, varscan2
- SVIL | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100881260; called by muse, mutect2
- TENM3 | c.2585G>A p.S862N | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as rs757433932, COSV101305117; called by muse, mutect2, varscan2
- TMEM204 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs778930774, COSV99559984; called by muse, mutect2, varscan2
- TRPM6 | c.5557C>T p.P1853S | Missense Mutation (SNP) | VAF 93/230 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV100666331; called by muse, mutect2, varscan2
- TTN | c.16345G>T p.D5449Y (on ENST00000591111; = p.D4522Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/74 reads (39%) | PolyPhen probably damaging (0.999); catalogued as COSV100612865; called by muse, mutect2, varscan2
- ZNF143 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.133); catalogued as COSV100217831; called by muse, mutect2, varscan2
- ZNF275 | c.980G>T p.G327V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs367933615, COSV100936253; called by muse, mutect2, varscan2
- ZNF517 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 51/80 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as rs767292151, COSV63465175; called by muse, mutect2, varscan2
- ZNF687 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs770670817, COSV100134193; called by muse, mutect2, varscan2
- ZNRD2 | c.332C>G p.S111C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as rs1226843172, COSV100326121; called by muse, mutect2, varscan2
- PIK3R1 | c.1372_1374dup p.E458dup (on ENST00000521381 / NM_181523.3; = p.E188dup on NM_181504.4) | In Frame Ins (INS) | VAF 13/20 reads (65%) | called by mutect2, pindel, varscan2
- ADAMTS16 | c.3438T>C p.V1146= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV99941218; called by muse, mutect2
- COL27A1 | c.4996T>C p.L1666= | Silent (SNP) | VAF 34/40 reads (85%) | catalogued as COSV100621009; called by muse, mutect2, varscan2
- EVC | c.543C>T p.A181= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV99381769; called by muse, mutect2, varscan2
- LGALS3BP | c.1659G>A p.S553= | Silent (SNP) | VAF 22/27 reads (81%) | catalogued as rs777190093, COSV53165272, COSV53166206; called by muse, mutect2, varscan2
- TRAF4 | c.720G>A p.K240= | Silent (SNP) | VAF 22/24 reads (92%) | catalogued as COSV99286465; called by muse, mutect2, varscan2
- ZNF778 | c.1029G>A p.G343= | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as COSV100124425; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505415 T>G | 5'Flank (SNP) | VAF 38/140 reads (27%) | called by muse, mutect2, varscan2
